Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7681, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7681-01A (Primary Tumor).

Microscopic

Sections demonstrate a glioma with biphenotypical features including both astrocytic and oligodendroglial components. The oligodendroglial component demonstrates individual tumor cells with round nuclei and prominent perinuclear halo formation. They are embedded in a fibrillary background containing thin branching vessels and microcystic change. Numerous microgemistocytes are interspersed throughout the tumor. The astrocytic component consists of neoplastic glial cells with oval nuclei and prominent fibrillary processes. The tumor cells diffusely infiltrate the adjacent brain parenchyma. Overall, the cytologic atypia is mild to moderate. Neither necrosis nor microvascular proliferation is seen. Only a rare mitotic figure is identified. These histologic features are consistent with an oligoastrocytoma

Addendum

A MIB-1 labeling index ranges up to 2.4% consistent with a low grade glioma

Diagnosis

Oligoastrocytoma, low grade II

Source: NCI Genomic Data Commons file 24878cbc-bb7c-4e05-9e44-24b013b12210 (TCGA-HT-7681.D6CA1FD7-EDD7-432C-A296-1CCE50CE71DF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).